Gene-level copy-number profile of tumor specimen HTMCP-03-06-02054-01B from CGCI case HTMCP-03-06-02054, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02054-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2cb4c39b-e508-47a6-8b58-3f6bf2033927.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02054-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/6df80c3d-7d23-4b5e-a2d1-e80c9c375773

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 7,502; copy number 2: 42,531; copy number 3: 5,819; copy number 4: 2,431; copy number 5: 41; copy number 6: 48; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,200,756–7,385,558, 16 genes: AF228730.1, AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P, FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C.
- chr11:134,331,874–135,075,908, 11 genes: GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.1, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:73,749,517–73,915,340, 3 genes, copy number 5: RNA5SP50, AL591463.1, RNU4ATAC8P.
- chr3:177,019,340–177,767,379, 13 genes, copy number 5: TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4.
- chr3:189,631,389–189,897,276, 1 gene, copy number 6 (within-gene range 4–6): TP63.
- chr3:189,829,922–189,830,009, 1 gene, copy number 6: MIR944.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,257,879–38,340,998, 14 genes, copy number 5: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 5 (within-gene range 2–5): TRGV5P, TRGV5.
- chr8:42,541,155–42,555,195, 1 gene, copy number 6 (within-gene range 1–6): SMIM19.
- chr9:65,189,995–65,230,861, 3 genes, copy number 5: BMS1P12, AL512605.1, AL512605.2.
- chr14:22,197,446–22,497,718, 44 genes, copy number 6: AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr15:21,980,277–21,981,245, 1 gene, copy number 7: OR11J6P.
- chr20:16,670,641–16,684,404, 2 genes, copy number 5: Y_RNA, AL135938.1.

Autosomal genes at a single copy (total copy number 1): 7,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
